Somatic mutation profile of tumor specimen HTMCP-03-06-02399-01A (aliquot HTMCP-03-06-02399-01A-01D-10409) from CGCI case HTMCP-03-06-02399, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 42.0 years (15,345 days).
Specimen HTMCP-03-06-02399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 738c3490-55e9-484c-875d-a216e760f9b3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02399-10A (Blood Derived Normal), aliquot HTMCP-03-06-02399-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0e92ee8-cd90-496c-af0c-a4eab8ec282e

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Intron 1, Frame Shift Del 1, 3'Flank 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs755116860, COSV62322148; called by muse, mutect2, varscan2
- CLTCL1 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs370323620; called by muse, mutect2, varscan2
- KLC4 | c.210G>C p.Q70H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as rs767408242; called by muse, varscan2
- MAST4 | c.3854C>T p.S1285F (on ENST00000403625 / NM_001164664.2; = p.S1096F on NM_015183.3) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1283923527; called by muse, mutect2, varscan2
- NRXN1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as rs201966126, COSV101277659, COSV68003819; called by muse, mutect2
- PIEZO2 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs1184679155; called by muse, mutect2, varscan2
- PMFBP1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs778421999; called by muse, mutect2, varscan2
- PREX2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866864487, COSV55780007; called by muse, mutect2, varscan2
- TTN | c.2950G>A p.E984K (on ENST00000591111; = p.E938K on NM_003319.4) | Missense Mutation (SNP) | VAF 38/135 reads (28%) | PolyPhen probably damaging (0.994); catalogued as rs753071669, COSV100604001, COSV60116882; called by muse, mutect2, varscan2
- ZNF43 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs1242314715; called by muse, mutect2, varscan2
- ARHGEF9 | c.1247_1250dup p.R418Afs*15 | Frame Shift Ins (INS) | VAF 54/319 reads (17%) | called by mutect2, varscan2
- CCDC114 | c.1471-4G>T | Splice Region (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
- DNAH10 | c.3991C>A p.L1331I (on ENST00000409039; = p.L1270I on NM_207437.3) | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FASN | c.6025G>T p.A2009S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GBF1 | c.1213A>G p.I405V (on ENST00000369983 / NM_001377137.1; = p.I404V on NM_004193.3) | Missense Mutation (SNP) | VAF 94/169 reads (56%) | SIFT tolerated (0.72); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GREB1 | c.2906A>G p.H969R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- KSR1 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RANBP6 | c.762del p.V255Yfs*9 | Frame Shift Del (DEL) | VAF 66/403 reads (16%) | called by mutect2, pindel, varscan2
- RYR2 | c.9129G>C p.R3043S | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF544 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 58/226 reads (26%) | called by muse, mutect2, varscan2
- KIF3C | c.144C>T p.R48= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs750301291; called by muse, mutect2, varscan2
- MAST4 | c.3855C>T p.S1285= (on ENST00000403625 / NM_001164664.2; = p.S1096= on NM_015183.3) | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs1457329656; called by muse, mutect2, varscan2
- PCDHA11 | c.102C>T p.S34= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV56482014; called by muse, mutect2
- TPH2 | c.984G>A p.A328= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as rs766153353; called by muse, mutect2, varscan2
- LONRF1 | c.1114-185G>A | Intron (SNP) | VAF 24/97 reads (25%) | catalogued as rs140643429; called by muse, mutect2, varscan2
- RNU6-713P | chr12:40550701 G>A | 3'Flank (SNP) | VAF 28/155 reads (18%) | catalogued as rs546664951; called by muse, mutect2, varscan2
